Somatic mutation profile of tumor specimen C3L-08157-02 (aliquot CPT0512060006) from CPTAC case C3L-08157, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 70.2 years (25,629 days).
Specimen C3L-08157-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30a778ea-a4bc-4af5-b17f-8f433d602016.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08157-31 (Blood Derived Normal), aliquot CPT0512040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c013cff7-e4f8-42ba-993c-a739ed861013

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 24, Silent 8, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377767382, CM040451, CM100521, COSV61684983, COSV61685664; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 17/404 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2
- AGBL1 | c.2720A>C p.K907T | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV66868237; called by muse, mutect2
- CCDC185 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 45/584 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.729); catalogued as rs1050895261, COSV64820780; called by muse, mutect2
- CD5L | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs749053734, COSV63820970, COSV63822649; called by muse, mutect2
- CDH1 | c.766A>T p.N256Y | Missense Mutation (SNP) | VAF 41/362 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99028455, COSV99932721; called by muse, mutect2, varscan2
- OR13C4 | c.957A>C p.*319Yext*? | Nonstop Mutation (SNP) | VAF 9/125 reads (7%) | catalogued as COSV52928069, COSV99470294; called by muse, mutect2
- TMEM225 | c.397T>G p.S133A | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as rs538371635; called by muse, mutect2
- CHFR | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHST11 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COLEC12 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.043); called by muse, mutect2
- DCSTAMP | c.942T>G p.D314E | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FANCB | c.974T>G p.L325R | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2
- GABRG1 | c.877T>G p.W293G | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- KCNK6 | c.191A>T p.E64V | Missense Mutation (SNP) | VAF 37/585 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2
- KMT2A | c.10875T>G p.N3625K | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2
- KRTAP4-11 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 27/840 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- MICALL1 | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- OR5H15 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 17/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLCL1 | c.2951T>G p.M984R | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- PLXNB3 | c.2551T>G p.L851V | Missense Mutation (SNP) | VAF 23/504 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0.05); called by muse, mutect2
- PPP4R3C | c.1798A>C p.N600H | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPANXN3 | c.23C>A p.T8N | Missense Mutation (SNP) | VAF 11/307 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF43 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ZNF430 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- EFCAB5 | c.417G>A p.L139= | Silent (SNP) | VAF 14/307 reads (5%) | catalogued as rs1442836095, COSV57926222; called by muse, mutect2
- FAM20A | c.486C>A p.V162= | Silent (SNP) | VAF 15/450 reads (3%) | called by muse, mutect2
- FAM83H | c.2925C>G p.P975= | Silent (SNP) | VAF 38/643 reads (6%) | called by muse, mutect2
- FBRSL1 | c.1179G>A p.P393= | Silent (SNP) | VAF 36/608 reads (6%) | catalogued as rs1033463179; called by muse, mutect2
- HAO2 | c.42A>G p.R14= | Silent (SNP) | VAF 13/346 reads (4%) | called by muse, mutect2
- MCM3AP | c.1785G>A p.L595= | Silent (SNP) | VAF 24/386 reads (6%) | catalogued as rs374057302, COSV52447396; called by muse, mutect2
- PLCL1 | c.2385T>G p.R795= | Silent (SNP) | VAF 18/292 reads (6%) | called by muse, mutect2
- TMIGD3 | c.82C>T p.L28= | Silent (SNP) | VAF 19/282 reads (7%) | called by muse, mutect2
